Surgical pathology report (de-identified scan), TCGA case TCGA-DD-A4NI, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DD-A4NI-01A (Primary Tumor).

DIAGNOSIS:

- A. Gallbladder, cholecystectomy: Acute and chronic cholecystitis and cholelithiasis. A single (1) cystic duct reactive lymph node.
- B. Liver, segment IVa, biopsy: Focus of atypical hepatocytes with architectural cribriforming, consistent with hepatocellular carcinoma arising in a background of steatohepatitis (these features are best seen on the frozen section slide).
- C. Liver, segment II, biopsy: Subcapsular lipoma (0.5 cm). The underlying liver parenchyma shows marked steatohepatitis.
- D. Liver, left hepatectomy: Grade 1 - 2 (of 4) hepatocellular carcinoma, forming a well-defined, lobulated and hemorrhagic dominant mass (4.8 x 4.2 x 3.7 cm) with biopsy effect in segment IVb of the liver. Situated roughly 5 cm superior to this tumor, in segment IVa (clinical), is a second nodule of grade 1 - 2 (of 4) hepatocellular carcinoma that is much less distinct grossly with an estimated greatest linear extent of about 1.5 cm. This tumor also displays needle tract effect (see part B above). Near the end of segment II is a cautery defect status-post wedge biopsy (see part C above). The background liver shows gross and microscopic evidence of steatohepatitis without cirrhosis. Random sections of background liver evaluated microscopically show "clonal" expansions of hepatocytes with some architectural and cytologic atypia best viewed as physiologic in nature. There are also many bile duct hamartomas identified grossly and microscopically ranging in size from 0.2 cm to 0.5 cm in greatest dimension. The margins of resection are negative for malignancy (closest tumor free margin estimated at roughly 0.5 cm from the smaller cancer in segment IVa).

ICD 6-3
Carcinoma, hepatocellular NOS
8170/3
Site: Liver C22.0
JW 12/24/12

9/20/12

Source: NCI Genomic Data Commons file 8ee4c286-7215-4d1c-8847-efca5b9af3be (TCGA-DD-A4NI.7D4F801A-187C-4B20-96B3-98313D5252E3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).